Somatic mutation profile of tumor specimen C3L-00881-73 (aliquot CPT0017040007_1) from CPTAC case C3L-00881, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.3 years (29,330 days).
Specimen C3L-00881-73: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d21ad8d0-8cba-42a5-874b-86826e826d4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00881-31 (Blood Derived Normal), aliquot CPT0015340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edde72bd-5d39-4a84-845e-31d94940c8ae

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Splice Site 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 36/494 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- ASIC3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 42/746 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs1414105389; called by muse, mutect2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2
- KCNA3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV63902586; called by muse, mutect2
- LAMA1 | c.3539G>A p.R1180H | Missense Mutation (SNP) | VAF 70/1503 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs543432434, COSV67538610; called by muse, mutect2
- LRPPRC | c.3985+1G>C p.X1329_splice | Splice Site (SNP) | VAF 10/236 reads (4%) | catalogued as rs1282249251; called by muse, mutect2
- PCDHA9 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 92/2242 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV65333780; called by muse, mutect2
- POMT2 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 49/1194 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1337866102; called by muse, mutect2
- VPS13C | c.10414+2T>C p.X3472_splice (on ENST00000644861 / NM_020821.3; = p.X3429_splice on NM_017684.5) | Splice Site (SNP) | VAF 20/214 reads (9%) | catalogued as rs762083465; called by muse, mutect2
- ASXL1 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 24/665 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHAT | c.2097C>A p.C699* | Nonsense Mutation (SNP) | VAF 36/962 reads (4%) | called by muse, mutect2
- HSPB9 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 57/826 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.368); called by muse, mutect2
- LY6G6E | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 82/1313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEX1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- SAMD9 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.295); called by muse, mutect2
- SENP2 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.458); called by muse, mutect2
- SLITRK6 | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- STOX1 | c.2299A>C p.N767H | Missense Mutation (SNP) | VAF 26/754 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- TPRN | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- BAHCC1 | c.1134G>A p.P378= | Silent (SNP) | VAF 13/377 reads (3%) | catalogued as rs1555652845; called by muse, mutect2
- FLG2 | c.6468A>G p.R2156= | Silent (SNP) | VAF 29/500 reads (6%) | called by muse, mutect2
- GPR50 | c.1668C>T p.D556= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as rs747548013, COSV54441311; called by muse, mutect2, varscan2
- H3C11 | c.246T>C p.D82= | Silent (SNP) | VAF 46/830 reads (6%) | catalogued as rs1185788053; called by muse, mutect2
- SLC35A2 | c.843C>T p.G281= | Silent (SNP) | VAF 37/350 reads (11%) | catalogued as rs782406133; called by muse, mutect2, varscan2
- ATP1A1 | chr1:116405719 A>G | 3'Flank (SNP) | VAF 15/405 reads (4%) | called by muse, mutect2
